Surgical pathology report (de-identified scan), TCGA case TCGA-IC-A6RE, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-IC-A6RE-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: ESOPHAGUS, 25 CM, BIOPSY -

- A. REACTIVE SQUAMOUS MUCOSA.
- B. NO GLANDULAR MUCOSA PRESENT.

ICD-O-3

PART 2: LYMPH NODE, PARAESOPHAGEAL NEAR LEFT CRUZ, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

Adenocarcinoma NOS
8140/3

PART 3: LYMPH NODE, RIGHT PLEURAL, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

Site Distal third of
esophagus C15.5

PART 4: LYMPH NODE, NEAR PERICARDIUM, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 5: TISSUE NEAR BASE OF LEFT GASTRIC, BIOPSY -
THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

gn 8/2/13

PART 6: TISSUE NEAR BASE OF RIGHT CRUZ, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: LYMPH NODE, NEAR BRONCHUS INTERMEDIUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 8: LYMPH NODE, LEVEL 4, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 9: LYMPH NODE, LEVEL 7 NEAR LEFT MAIN STEM BRONCHUS, BIOPSY -
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 10: LYMPH NODE, LEVEL 7 NEAR AORTA, BIOPSY -
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 11: LYMPH NODE, LEVEL 7 NEAR LEFT PLEURA, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 12: LEVEL 7 TISSUE, BIOPSY -
BLOOD ONLY, NO LYMPH NODE IDENTIFIED.

PART 13: LYMPH NODE, PERIESOPHAGEAL NEAR VAGUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 14: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY -

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA, 3.5 CM, OF THE DISTAL ESOPHAGUS WITH FOCAL INVASION INTO THE SUPERFICIAL MUSCULARIS PROPRIA AND ASSOCIATED WITH BARRETT'S MUCOSA WITH HIGH-GRADE DYSPLASIA.
- B. ANGIOLYMPHOMATIC INVASION IDENTIFIED.
- C. ALL SURGICAL MARGINS (DISTAL, PROXIMAL, AND CIRCUMFERENTIAL) ARE NEGATIVE FOR TUMOR.
- D. FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).
- E. PATHOLOGIC STAGE: pT2 N1.

PART 15: NEW ESOPHAGEAL MARGIN, RESECTION -
SEGMENT OF ESOPHAGUS, NEGATIVE FOR TUMOR.

PART 16: GASTRIC RINGS, RESECTION -
SEGMENTS OF ESOPHAGUS AND STOMACH, NEGATIVE FOR TUMOR.

PART 17: FINAL GASTRIC MARGIN, RESECTION -
NEGATIVE FOR TUMOR.

PART 18: GASTROESOPHAGEAL FAT, RESECTION -
NINE LYMPH NODES, NEGATIVE FOR TUMOR (0/9).

PART 19: LYMPH NODE, SUBCARINAL NEAR LEFT MAIN BRONCHUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

[page 2 of 2]
PART 20: LYMPH NODE, SUBCARINAL NEAR AZYGOUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 21: LYMPH NODE, SUBCARINAL, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 22: LYMPH NODE, GASTRIC FAT, BIOPSY -
METASTATIC ADENOCARCINOMA IN ONE LYMPH NODE (1/1).

PART 23: LYMPH NODE, NEAR GE JUNCTION, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 24: LYMPH NODE, PROXIMAL PARAESOPHAGEAL, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 25: LYMPH NODE, SUBCARINAL NEAR ESOPHAGUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 26: LYMPH NODE, SUBCARINAL NEAR LEFT ATRIUM, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 27: LYMPH NODE, FAT PAD, BIOPSY -
METASTATIC ADENOCARCINOMA IN ONE LYMPH NODE (1/1).

PART 28: LYMPH NODE, SUBCARINAL NEAR RIGHT MAIN BRONCHUS, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Distal (lower thoracic) esophagus (epicenter 5-10cm from EGJ)
TUMOR SIZE: Greatest dimension: 3.5 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM)
pT2
pN1
Number of lymph nodes examined: 38
Number of lymph nodes involved: 2
17 or more regional lymph nodes were identified
pM Not applicable
No prior treatment

**PRIOR TREATMENT:
MARGINS**

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 8 mm
Specify margin: Circumferential (adventitial)

ANGIOLYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)
High grade dysplasia

Source: NCI Genomic Data Commons file 631f6ff4-cc0e-4f2e-be07-0aba0475a051 (TCGA-IC-A6RE.21C5FE38-D795-4B2E-A876-2933A618B034.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).